Somatic mutation profile of tumor specimen 0DYVSP from CCDI case PBCMAG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 20.3 years (7,428 days).
Specimen 0DYVSP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 987b1d6e-c4e3-4b75-a829-9fa7b079dee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYVSC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ebb6ac5-7155-4746-bbd2-09ab92261703

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/972 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LACTBL1 | c.314C>A p.P105H (on ENST00000618559; = p.P134H on NM_001289974.2) | Missense Mutation (SNP) | VAF 173/1045 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760527231; called by muse, mutect2, varscan2
- PCGF6 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 32/561 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- USP15 | c.348+475C>G | Intron (SNP) | VAF 52/293 reads (18%) | called by muse, mutect2, varscan2
